Somatic mutation profile of tumor specimen MMRF_2675_1_BM_CD138pos (aliquot MMRF_2675_1_BM_CD138pos_T1_KHS5U_L13792) from MMRF case MMRF_2675, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.9 years (22,227 days).
Specimen MMRF_2675_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5352db8-83fe-4d58-b8b8-949cc9ee21c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2675_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2675_1_PB_WBC_C3_KHS5U_L13793; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3b81bd4-1bef-41ff-8ff1-0a3d95ee549e

The open-access MAF lists 149 somatic variants for this specimen: 74 protein-altering or splice-affecting, 16 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, 3'UTR 30, Silent 16, Intron 14, 5'UTR 6, Nonsense Mutation 4, 3'Flank 3, RNA 3, 5'Flank 3, Splice Site 2, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 55/487 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- ADA2 | c.1483G>T p.E495* (on ENST00000262607; = p.E254* on NM_177405.3) | Nonsense Mutation (SNP) | VAF 203/397 reads (51%) | catalogued as COSV52833506; called by mutect2, varscan2
- ANKRD17 | c.5699T>C p.F1900S | Missense Mutation (SNP) | VAF 148/703 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs781546161; called by muse, mutect2, varscan2
- ASB15 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 66/962 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs370081452; called by muse, mutect2
- BCL3 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 117/293 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV51233862; called by muse, mutect2, varscan2
- C11orf58 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 60/1712 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV57178882; called by muse, mutect2
- CYB5R4 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs1012959984, COSV63747053; called by muse, mutect2, varscan2
- DNAH8 | c.6845G>A p.R2282H | Missense Mutation (SNP) | VAF 227/468 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1253356713, COSV59478663; called by muse, mutect2, varscan2
- DUOX2 | c.3163G>A p.V1055M | Missense Mutation (SNP) | VAF 93/1166 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs367803824, COSV66530997; called by muse, mutect2
- GGT5 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1161844017, COSV99571590; called by muse, mutect2
- H2AC17 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 304/695 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs191325870, COSV58152870; called by muse, mutect2, varscan2
- IGHV1-69 | c.342C>G p.Y114* | Nonsense Mutation (SNP) | VAF 54/125 reads (43%) | catalogued as rs373289957; called by muse, mutect2, varscan2
- IGHV1-69D | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 258/499 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1367696485; called by muse, varscan2
- IGHV2-70 | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs370737142; called by muse, varscan2
- IGHV2-70 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 108/223 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs546262332; called by muse, varscan2
- LCN2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 90/668 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs370705191; called by muse, mutect2, varscan2
- LRP4 | c.4054C>T p.P1352S | Missense Mutation (SNP) | VAF 185/758 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1172217709; called by muse, mutect2, varscan2
- MCM2 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 147/587 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.564); catalogued as rs1307685065, COSV54036291; called by muse, mutect2, varscan2
- MDGA2 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 180/385 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as rs1252594859; called by muse, varscan2
- NEK10 | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 54/768 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs775535920; called by muse, mutect2
- NGDN | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 130/255 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs566567181, COSV101238937; called by muse, varscan2
- PCDHA11 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 107/534 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs987284077, COSV56494066; called by muse, mutect2, varscan2
- PLEKHG5 | c.979C>T p.R327W (on ENST00000400915 / NM_001042663.3; = p.R290W on NM_020631.6) | Missense Mutation (SNP) | VAF 247/629 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as rs751787031; called by muse, mutect2, varscan2
- PLG | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 171/346 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs752373837, COSV57517969; called by muse, mutect2, varscan2
- PPFIA2 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV61046657, COSV61050843; called by muse, mutect2, varscan2
- RIN1 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 140/697 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.111); catalogued as rs767048351; called by muse, varscan2
- RP1L1 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 30/387 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs1187441272, COSV66754347; called by muse, mutect2
- SF3B3 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 107/341 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV56787788; called by muse, mutect2, varscan2
- SIGLEC9 | c.135C>A p.Y45* | Nonsense Mutation (SNP) | VAF 183/1252 reads (15%) | catalogued as rs1697545; called by muse, mutect2, varscan2
- SLC12A7 | c.1396+1G>A p.X466_splice | Splice Site (SNP) | VAF 47/325 reads (14%) | catalogued as rs1350415878; called by muse, mutect2, varscan2
- SMARCD1 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV67411587; called by muse, mutect2, varscan2
- TM4SF4 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 12/410 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV59515973, COSV59516693; called by muse, mutect2
- TMC8 | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 20/518 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV100573744; called by muse, mutect2
- TRIM66 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs906389780; called by muse, mutect2
- TRPV3 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 96/431 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776459642, COSV56790382, COSV56791850; called by muse, mutect2, varscan2
- UROC1 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 110/488 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1195858314, COSV52039422; called by muse, mutect2, varscan2
- VPS37D | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs868926525; called by muse, mutect2, varscan2
- ACSM1 | c.831G>C p.W277C | Missense Mutation (SNP) | VAF 17/319 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.132); called by muse, mutect2
- AHNAK | c.13958C>T p.P4653L | Missense Mutation (SNP) | VAF 66/1318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARFGEF2 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 37/421 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- C10orf82 | c.102C>A p.D34E | Missense Mutation (SNP) | VAF 142/266 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.373); called by mutect2, varscan2
- C10orf90 | c.2038C>T p.L680F | Missense Mutation (SNP) | VAF 183/377 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CA11 | c.824A>T p.N275I | Missense Mutation (SNP) | VAF 19/458 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CLOCK | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2
- DSC1 | c.1364C>G p.T455S | Missense Mutation (SNP) | VAF 154/678 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EID3 | c.197T>C p.L66S | Missense Mutation (SNP) | VAF 251/580 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FILIP1L | c.2614C>T p.H872Y (on ENST00000354552 / NM_182909.3; = p.H632Y on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/988 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.261); called by muse, mutect2
- GAS7 | c.565G>C p.E189Q (on ENST00000432992 / NM_201433.2; = p.E49Q on NM_003644.3) | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2
- GJE1 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- HSDL2 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 236/744 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- IGHV1-69D | c.342C>G p.Y114* | Nonsense Mutation (SNP) | VAF 163/382 reads (43%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 212/471 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, varscan2
- IGHV2-70 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 101/205 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- IL7 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 109/502 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRS1 | c.1324T>A p.F442I | Missense Mutation (SNP) | VAF 52/564 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.444); called by muse, mutect2
- ITGA7 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 51/414 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ME3 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 56/780 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- NCOA7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 68/786 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- NELL1 | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 167/1075 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- NFKBIA | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 44/695 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, mutect2
- PARP1 | c.2138T>A p.L713H | Missense Mutation (SNP) | VAF 156/327 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PGLYRP2 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 41/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by mutect2, varscan2
- PIAS2 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 264/780 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, varscan2
- PLCD3 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 177/357 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRAMEF12 | c.1147T>C p.F383L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- RNMT | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBF2 | c.5406del p.S1803Afs*74 | Frame Shift Del (DEL) | VAF 50/590 reads (8%) | called by mutect2, pindel
- SETMAR | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 53/990 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); called by muse, mutect2
- SP8 | c.-33-2A>G | Splice Site (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- TCEANC | c.1036A>G p.S346G (on ENST00000380600 / NM_001297563.2; = p.S376G on NM_152634.4) | Missense Mutation (SNP) | VAF 91/99 reads (92%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- TRAF3IP2 | c.1547T>G p.F516C | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRUB1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 305/667 reads (46%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF578 | c.806A>T p.N269I | Missense Mutation (SNP) | VAF 62/926 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF717 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- BAHCC1 | c.1758C>T p.V586= | Silent (SNP) | VAF 120/307 reads (39%) | called by muse, mutect2, varscan2
- CHD5 | c.3990G>A p.Q1330= | Silent (SNP) | VAF 56/211 reads (27%) | called by muse, mutect2, varscan2
- DCSTAMP | c.111T>C p.C37= | Silent (SNP) | VAF 34/464 reads (7%) | called by muse, mutect2
- ELF3 | c.867C>T p.N289= | Silent (SNP) | VAF 238/524 reads (45%) | catalogued as rs754686422; called by muse, varscan2
- IGHV2-70 | c.306A>G p.T102= | Silent (SNP) | VAF 142/306 reads (46%) | catalogued as rs377122389; called by muse, varscan2
- IGHV2-70 | c.246A>G p.T82= | Silent (SNP) | VAF 266/534 reads (50%) | catalogued as rs367734033; called by muse, varscan2
- ITGAE | c.3207T>A p.A1069= | Silent (SNP) | VAF 170/400 reads (43%) | called by mutect2, varscan2
- KMT2C | c.144C>T p.F48= | Silent (SNP) | VAF 82/767 reads (11%) | called by muse, mutect2, varscan2
- LZTR1 | c.702T>C p.A234= | Silent (SNP) | VAF 131/283 reads (46%) | called by muse, mutect2, varscan2
- MEF2B | c.939C>T p.L313= | Silent (SNP) | VAF 177/494 reads (36%) | called by muse, mutect2, varscan2
- NRP1 | c.1083C>T p.D361= | Silent (SNP) | VAF 316/716 reads (44%) | catalogued as rs550303286, COSV99587629; called by muse, varscan2
- PHF8 | c.1890G>A p.K630= (on ENST00000357988 / NM_001184896.1; = p.K594= on NM_015107.3) | Silent (SNP) | VAF 10/251 reads (4%) | called by muse, mutect2
- PXDN | c.2688C>T p.S896= | Silent (SNP) | VAF 56/433 reads (13%) | catalogued as rs747948602, COSV53240194; called by muse, mutect2, varscan2
- SLC16A6 | c.189C>T p.I63= | Silent (SNP) | VAF 18/311 reads (6%) | called by muse, mutect2
- SPSB4 | c.471C>T p.P157= | Silent (SNP) | VAF 77/517 reads (15%) | catalogued as rs754566043; called by muse, mutect2, varscan2
- ZNF865 | c.3168G>T p.G1056= | Silent (SNP) | VAF 14/410 reads (3%) | called by muse, mutect2
- ABCF3 | c.-164G>A | 5'UTR (SNP) | VAF 24/616 reads (4%) | called by muse, mutect2
- ACTN4 | c.1442+13T>G | Intron (SNP) | VAF 146/911 reads (16%) | called by muse, mutect2, varscan2
- ALPP | c.*554C>G | 3'UTR (SNP) | VAF 212/898 reads (24%) | called by mutect2, varscan2
- ANAPC2 | c.1169-95A>G | Intron (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- ANXA2R | c.*203_*206del | 3'UTR (DEL) | VAF 15/128 reads (12%) | called by pindel, varscan2
- APOLD1 | c.*118G>C | 3'UTR (SNP) | VAF 259/521 reads (50%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020969 C>G | 5'Flank (SNP) | VAF 268/620 reads (43%) | catalogued as COSV55849224, COSV55851032; called by muse, varscan2
- C20orf194 | c.*1614G>A | 3'UTR (SNP) | VAF 119/240 reads (50%) | catalogued as rs868274823; called by muse, mutect2, varscan2
- C5orf66-AS2 | n.1733T>A | RNA (SNP) | VAF 143/547 reads (26%) | called by muse, mutect2, varscan2
- CCN1 | c.843+12C>T | Intron (SNP) | VAF 14/380 reads (4%) | called by muse, mutect2
- CEP170P1 | n.3753C>T | RNA (SNP) | VAF 31/648 reads (5%) | catalogued as rs779952978; called by muse, mutect2
- CRB1 | c.4005+1955C>G | Intron (SNP) | VAF 9/208 reads (4%) | called by muse, mutect2
- DCAF11 | c.*551A>C | 3'UTR (SNP) | VAF 231/544 reads (42%) | called by muse, mutect2, varscan2
- DERL3 | c.-11G>T | 5'UTR (SNP) | VAF 146/328 reads (45%) | called by muse, mutect2, varscan2
- ELK3 | c.*875T>C | 3'UTR (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- FAM180A | c.*8G>C | 3'UTR (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- FUT8 | c.*468T>C | 3'UTR (SNP) | VAF 57/144 reads (40%) | called by muse, mutect2, varscan2
- GABRA2 | c.-66T>C | 5'UTR (SNP) | VAF 92/766 reads (12%) | called by muse, varscan2
- GLG1 | c.*1268C>G | 3'UTR (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- GNL1 | c.*3527A>C | 3'UTR (SNP) | VAF 226/467 reads (48%) | called by muse, mutect2, varscan2
- GPC5 | c.*69T>A | 3'UTR (SNP) | VAF 22/692 reads (3%) | called by muse, mutect2
- GRIN1 | c.*1171A>G | 3'UTR (SNP) | VAF 158/512 reads (31%) | called by muse, mutect2, varscan2
- HSPA9 | c.*4T>C | 3'UTR (SNP) | VAF 62/1026 reads (6%) | catalogued as rs368382143; called by muse, mutect2
- KIAA0825 | c.970+304A>G | Intron (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- KPNA1 | c.*664A>C | 3'UTR (SNP) | VAF 20/409 reads (5%) | called by muse, mutect2
- LARP4 | c.*354T>C | 3'UTR (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- LPIN2 | c.*1620A>C | 3'UTR (SNP) | VAF 52/233 reads (22%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851126 T>A | 5'Flank (SNP) | VAF 318/727 reads (44%) | catalogued as rs569234583; called by mutect2, varscan2
- MMAA | c.562+134G>A | Intron (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- MPDZ | c.*57A>G | 3'UTR (SNP) | VAF 46/205 reads (22%) | called by muse, mutect2, varscan2
- NACA | c.71-4285C>A | Intron (SNP) | VAF 188/420 reads (45%) | called by muse, mutect2, varscan2
- NAV3 | c.*1122G>T | 3'UTR (SNP) | VAF 122/280 reads (44%) | catalogued as COSV99887530; called by muse, mutect2, varscan2
- NOS1 | c.2532-2266G>A | Intron (SNP) | VAF 20/251 reads (8%) | catalogued as rs764460373, COSV57610175; called by muse, mutect2
- OR2M3 | chr1:248204175 A>T | 3'Flank (SNP) | VAF 66/132 reads (50%) | called by muse, mutect2
- PDE10A | c.*3535G>A | 3'UTR (SNP) | VAF 100/220 reads (45%) | called by muse, mutect2, varscan2
- PDE4B | c.281+73984A>T | Intron (SNP) | VAF 13/152 reads (9%) | called by muse, mutect2
- PDPK1 | c.*5235A>G | 3'UTR (SNP) | VAF 7/161 reads (4%) | called by muse, mutect2
- PHLDB1 | c.3416+41G>A | Intron (SNP) | VAF 58/804 reads (7%) | catalogued as rs781814738; called by muse, mutect2
- PLCD1 | c.*268A>C | 3'UTR (SNP) | VAF 142/211 reads (67%) | called by muse, mutect2, varscan2
- PRKAB1 | c.736-23A>C | Intron (SNP) | VAF 36/310 reads (12%) | called by muse, mutect2, varscan2
- PSMA2 | c.*556G>A | 3'UTR (SNP) | VAF 92/281 reads (33%) | called by muse, mutect2, varscan2
- PTMA | c.46-1230T>C | Intron (SNP) | VAF 13/116 reads (11%) | catalogued as rs1257071499; called by muse, mutect2
- PTPRD | c.*2228dup | 3'UTR (INS) | VAF 26/118 reads (22%) | catalogued as rs914144526; called by mutect2, varscan2
- RAB30 | chr11:82976874 T>A | 3'Flank (SNP) | VAF 20/374 reads (5%) | called by muse, mutect2
- RPS11 | chr19:49500846 T>C | 3'Flank (SNP) | VAF 68/120 reads (57%) | called by muse, varscan2
- SLC15A2 | c.*1472T>C | 3'UTR (SNP) | VAF 27/273 reads (10%) | called by muse, mutect2
- SNX15 | chr11:65027397 C>T | 5'Flank (SNP) | VAF 28/106 reads (26%) | catalogued as rs975830437; called by mutect2, varscan2
- SYNGAP1 | c.3885+44A>G | Intron (SNP) | VAF 247/685 reads (36%) | called by muse, mutect2, varscan2
- TEAD1 | c.*1925C>T | 3'UTR (SNP) | VAF 66/443 reads (15%) | called by muse, mutect2, varscan2
- TEAD1 | c.*4386C>A | 3'UTR (SNP) | VAF 91/236 reads (39%) | called by mutect2, varscan2
- TNFRSF8 | c.*282A>G | 3'UTR (SNP) | VAF 22/599 reads (4%) | called by muse, mutect2
- TRGV11 | c.-85C>T | 5'UTR (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- TRIM11 | c.*17G>A | 3'UTR (SNP) | VAF 79/220 reads (36%) | called by muse, mutect2, varscan2
- TYW3 | c.*1747G>A | 3'UTR (SNP) | VAF 32/90 reads (36%) | catalogued as rs1245525226; called by muse, mutect2, varscan2
- WNT1 | c.*170A>G | 3'UTR (SNP) | VAF 6/109 reads (6%) | catalogued as rs976735424; called by muse, mutect2
- WTAP | c.-385C>G | 5'UTR (SNP) | VAF 32/324 reads (10%) | called by muse, mutect2
- WWOX | c.517-108238C>T | Intron (SNP) | VAF 148/177 reads (84%) | catalogued as rs761491902, COSV100880495; called by muse, mutect2, varscan2
- YBX1P1 | n.951C>T | RNA (SNP) | VAF 205/492 reads (42%) | called by muse, mutect2, varscan2
- ZEB2 | c.-133T>C | 5'UTR (SNP) | VAF 92/295 reads (31%) | catalogued as rs1364591777; called by muse, mutect2, varscan2
